Somatic mutation profile of tumor specimen HTMCP-03-06-02397-01A (aliquot HTMCP-03-06-02397-01A-01D-10409) from CGCI case HTMCP-03-06-02397, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 30.2 years (11,047 days).
Specimen HTMCP-03-06-02397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3beed2c6-8695-40aa-bf4d-4c180d135672.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02397-10A (Blood Derived Normal), aliquot HTMCP-03-06-02397-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f1b2989-5741-4b92-b592-13a4048fa08b

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Frame Shift Del 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC2 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs375718755; called by muse, mutect2, varscan2
- C12orf50 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV53895860, COSV53896425; called by muse, mutect2, varscan2
- CACNA1B | c.3190G>A p.V1064I | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs1300134377, COSV53141285; called by muse, mutect2, varscan2
- CDH10 | c.2054del p.K685Sfs*34 | Frame Shift Del (DEL) | VAF 33/306 reads (11%) | catalogued as rs1561116064; called by mutect2, pindel, varscan2
- CDH2 | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as rs759639016, COSV99296474; called by muse, mutect2, varscan2
- KALRN | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as rs758996837, COSV53755450; called by muse, mutect2, varscan2
- MACF1 | c.9321C>G p.F3107L | Missense Mutation (SNP) | VAF 18/170 reads (11%) | catalogued as rs368806330, COSV57109615; called by muse, mutect2, varscan2
- PARD3B | c.811C>G p.Q271E | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62501422; called by muse, mutect2, varscan2
- PKHD1L1 | c.10672G>C p.E3558Q | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.415); catalogued as COSV101006555; called by muse, mutect2
- TMEM132E | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs760798406; called by muse, varscan2
- TRAPPC8 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs374865943; called by muse, mutect2, varscan2
- TTN | c.83404C>T p.P27802S (on ENST00000591111; = p.P20378S on NM_003319.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | PolyPhen probably damaging (0.998); catalogued as COSV60278573; called by muse, mutect2, varscan2
- ZBED2 | c.489G>T p.R163S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV51915237; called by muse, mutect2, varscan2
- ADCY5 | c.3193C>G p.Q1065E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- DYNC2H1 | c.11584C>T p.H3862Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF4G1 | c.3574G>A p.E1192K (on ENST00000346169 / NM_198241.3; = p.E997K on NM_004953.5) | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2
- LYST | c.7375T>C p.S2459P | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYT1L | c.2774C>T p.S925L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRQ | c.5587G>T p.E1863* (on ENST00000616559; = p.E1821* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 18/207 reads (9%) | called by muse, mutect2
- TCHH | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- TTLL5 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- UNC13A | c.3835_3841del p.D1279Kfs*6 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.1466C>G p.S489C | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZSCAN4 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CFAP46 | c.2463C>T p.D821= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs944691835; called by muse, mutect2, varscan2
- DNAH9 | c.4050C>A p.V1350= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs754070047, COSV52350078; called by muse, mutect2, varscan2
- FYB1 | c.6G>A p.A2= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as rs774770343, COSV60942303; called by muse, mutect2
- PHF8 | c.75G>T p.L25= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- PLEC | c.11544G>A p.K3848= (on ENST00000322810 / NM_201380.4; = p.K3738= on NM_000445.5) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs782560671, COSV100513540; called by muse, mutect2
- SHANK2 | c.1785C>T p.R595= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs553333717; called by muse, mutect2, varscan2
- SMARCA2 | c.1431C>A p.S477= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- SPG11 | c.1986A>C p.T662= | Silent (SNP) | VAF 61/236 reads (26%) | called by muse, mutect2, varscan2
- FAM86FP | n.154-38G>A | Intron (SNP) | VAF 46/194 reads (24%) | called by muse, mutect2, varscan2
